Somatic mutation profile of tumor specimen TCGA-PQ-A6FN-01A (aliquot TCGA-PQ-A6FN-01A-11D-A31L-08) from TCGA case TCGA-PQ-A6FN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,546 days).
Specimen TCGA-PQ-A6FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 333c0519-0b97-4fc3-8840-bdb82851c06d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PQ-A6FN-10A (Blood Derived Normal), aliquot TCGA-PQ-A6FN-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb33bf1-b58e-4b29-ab67-8d152abf10ab

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Splice Site 6, Nonsense Mutation 5, Frame Shift Del 5, In Frame Del 2, Frame Shift Ins 1, 5'Flank 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as rs786202534, COSV100523800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACY3 | c.526+1G>A p.X176_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54829129; called by muse, mutect2
- ADGRA3 | c.3503C>T p.S1168L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51564327; called by muse, mutect2, varscan2
- AL136295.1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV55779723; called by muse, mutect2, varscan2
- AMY2B | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV63715730; called by muse, mutect2, varscan2
- ANOS1 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs1393846121, COSV52921649; called by muse, mutect2, varscan2
- ATXN2L | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs987449959, COSV57372760; called by muse, mutect2, varscan2
- AUP1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV51208928; called by muse, mutect2, varscan2
- BCOR | c.1283A>G p.E428G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60710282; called by muse, mutect2, varscan2
- BEGAIN | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV62069162; called by muse, mutect2, varscan2
- C8orf76 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as rs564983874, COSV52690828; called by muse, mutect2
- CCDC178 | c.2357C>G p.S786* (on ENST00000383096 / NM_001105528.3; = p.S748* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV100284319, COSV55794120; called by muse, mutect2
- CHD3 | c.4711C>G p.L1571V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57876627; called by muse, mutect2, varscan2
- COMMD5 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs773870860, COSV57384140; called by muse, mutect2, varscan2
- COPG2 | c.2485G>A p.G829S | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554440286, COSV56227826; called by muse, mutect2
- CRISP3 | c.623G>A p.W208* (on ENST00000371159 / NM_001368123.1; = p.W190* on NM_006061.4) | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV53821444, COSV99538838; called by muse, mutect2
- CST8 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55671429; called by muse, mutect2, varscan2
- DEDD | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63502078; called by muse, mutect2, varscan2
- DIAPH2 | c.339G>C p.M113I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV61274628; called by muse, mutect2
- DNAH17 | c.7754G>A p.R2585H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778812435, COSV67749196; called by muse, mutect2, varscan2
- EDEM3 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV58925323; called by muse, mutect2
- ERICH1 | c.1258+1G>T p.X420_splice | Splice Site (SNP) | VAF 21/90 reads (23%) | catalogued as COSV50638805; called by muse, mutect2, varscan2
- EXOSC10 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752667734, COSV58666064; called by muse, mutect2, varscan2
- FAM135B | c.1378C>G p.L460V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV52733210, COSV52757897; called by muse, mutect2, varscan2
- FBXW7 | c.1095G>A p.W365* (on ENST00000281708 / NM_001349798.2; = p.W285* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | catalogued as COSV55954910; called by muse, mutect2, varscan2
- FLG | c.11002G>A p.E3668K | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1286387300, COSV100911394; called by muse, mutect2, varscan2
- GAD2 | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV52160670; called by muse, mutect2, varscan2
- GSTM1 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100564403; called by muse, varscan2
- HTR1E | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs771278269, COSV59507451; called by muse, mutect2, varscan2
- KCNA7 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs574043392, COSV99671882; called by muse, varscan2
- LAMA4 | c.1864G>C p.D622H (on ENST00000230538 / NM_001105206.3; = p.D615H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1219097715, COSV57899106; called by muse, mutect2, varscan2
- LDHD | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55581206; called by muse, mutect2, varscan2
- LIMK1 | c.1467G>C p.K489N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV60282321; called by muse, mutect2
- MBOAT2 | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV60009840; called by muse, mutect2, varscan2
- MSH4 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs763754874, COSV54204840, COSV99591272; called by muse, mutect2, varscan2
- MYH6 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769398160, COSV62451870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPH | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs561791494, COSV53635494; called by muse, mutect2, varscan2
- NLGN3 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV62444066; called by muse, mutect2, varscan2
- NVL | c.432del p.E145Kfs*9 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as COSV55873297; called by mutect2, pindel, varscan2
- OR2T4 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63543758, COSV63544321; called by muse, mutect2
- OR5H6 | c.775G>A p.A259T (on ENST00000642105; = p.A243T on NM_001005479.2) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV67351657; called by muse, mutect2, varscan2
- OR5M11 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV73141898; called by muse, mutect2, varscan2
- PGAM5 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58202399, COSV58203211; called by muse, varscan2
- PTCH2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764488358, COSV64711571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRD | c.4225G>C p.D1409H | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61956755; called by muse, mutect2, varscan2
- RB1 | c.2663+2T>G p.X888_splice | Splice Site (SNP) | VAF 31/127 reads (24%) | catalogued as COSV57296597, COSV57312328; called by muse, mutect2, varscan2
- REM1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs146287841; called by muse, mutect2, varscan2
- RNF213 | c.15618G>A p.M5206I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV60400624; called by muse, mutect2
- RSF1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV57836614, COSV57838115; called by muse, mutect2, varscan2
- SEMA5B | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV52101044; called by muse, mutect2, varscan2
- SMAD3 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV59285361; called by muse, mutect2, varscan2
- ST18 | c.416dup p.N139Kfs*9 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | catalogued as rs774059376; called by mutect2, varscan2
- SYTL3 | c.1222C>T p.L408F (on ENST00000611299 / NM_001242394.1; = p.L340F on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750348150, COSV51911503; called by muse, mutect2, varscan2
- TELO2 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV51978910; called by mutect2, varscan2
- TEX11 | c.2755G>T p.V919L (on ENST00000344304; = p.V904L on NM_031276.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60231108; called by muse, mutect2, varscan2
- TKTL2 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV54919601; called by muse, mutect2, varscan2
- TPM3 | c.775+1G>A p.X259_splice | Splice Site (SNP) | VAF 20/109 reads (18%) | catalogued as COSV55136934; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1228+1G>T p.X410_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100389662, COSV60676165; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1394G>A p.C465Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51956713; called by muse, mutect2, varscan2
- VCAN | c.2261C>G p.T754R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54108135, COSV99424941; called by muse, mutect2, varscan2
- WWC3 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749243703, COSV66504233; called by muse, mutect2, varscan2
- ZFP28 | c.2531C>G p.S844C | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV56736374; called by muse, mutect2, varscan2
- ZNF718 | c.539T>A p.F180Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV68140477; called by muse, mutect2, varscan2
- ABCA7 | c.4063del p.L1355Cfs*18 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17127_17155del p.S5710Cfs*7 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- GOLGB1 | c.4068_4083del p.T1358Lfs*22 | Frame Shift Del (DEL) | VAF 31/265 reads (12%) | called by mutect2, pindel
- LRRK2 | c.5717del p.K1906Rfs*12 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- TANC2 | c.4529_4546del p.Q1510_F1516delinsL | In Frame Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel
- TIAM1 | c.905_907del p.T302del | In Frame Del (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- ZNF488 | c.494A>T p.K165I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ALG2 | c.357C>A p.A119= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV53060067; called by muse, mutect2
- ANGEL1 | c.1824T>C p.A608= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV51873968; called by muse, mutect2
- B4GALT7 | c.117C>T p.L39= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV50353789; called by muse, mutect2, varscan2
- BPTF | c.1377A>G p.E459= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV58839682; called by muse, mutect2, varscan2
- CATSPERD | c.1875C>T p.T625= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs375337569, COSV58465823; called by muse, mutect2, varscan2
- DDX54 | c.2163G>A p.Q721= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV58374372; called by muse, mutect2, varscan2
- EPS8L3 | c.1518C>T p.P506= (on ENST00000361965 / NM_133181.4; = p.P476= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV62609742; called by muse, mutect2, varscan2
- GHSR | c.213C>T p.F71= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV53840132; called by muse, mutect2, varscan2
- HIPK4 | c.1113C>T p.L371= | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as COSV52521966; called by muse, mutect2, varscan2
- LRRC8A | c.1002C>T p.L334= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV52186816; called by muse, mutect2, varscan2
- MYOF | c.1996C>A p.R666= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV63705822; called by muse, mutect2, varscan2
- PIK3R5 | c.546G>A p.L182= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52654727, COSV52655131; called by muse, mutect2, varscan2
- PLAG1 | c.63G>A p.G21= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV57612543; called by muse, mutect2, varscan2
- PRPS1 | c.645G>A p.V215= | Silent (SNP) | VAF 107/385 reads (28%) | catalogued as COSV65054451; called by muse, mutect2, varscan2
- RNF213 | c.15474G>A p.L5158= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV60400604; called by muse, mutect2, varscan2
- SCFD2 | c.339C>T p.L113= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs770792741, COSV66373262; called by muse, mutect2, varscan2
- SH2D1A | c.213G>A p.G71= | Silent (SNP) | VAF 17/222 reads (8%) | catalogued as COSV63579239; called by muse, mutect2
- SIAH2 | c.411C>T p.P137= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57262423; called by muse, mutect2
- SUN3 | c.102C>T p.D34= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs768379894, COSV52049115, COSV52049450; called by muse, mutect2, varscan2
- AWAT1 | c.-1C>G | 5'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as COSV65738631; called by muse, varscan2
- RNU6-1178P | chr17:20895751 C>T | 5'Flank (SNP) | VAF 43/178 reads (24%) | catalogued as rs774595751, COSV100019031; called by muse, mutect2, varscan2
- RUNDC3A | c.1199-605C>T | Intron (SNP) | VAF 16/53 reads (30%) | catalogued as rs755230293, COSV56587864; called by muse, mutect2, varscan2
